Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040031-09A.3 (aliquot TARGET-15-SJMPAL040031-09A.3-01D) from TARGET case TARGET-15-SJMPAL040031, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.9 years (1,054 days).
Specimen TARGET-15-SJMPAL040031-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 064f636a-61c2-4770-a61e-ddcc9ef3fdd2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040031-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040031-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cd6f578a-f415-41d4-b6a6-ae9afc7dc04c

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 2, RNA 2, 5'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 59/151 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs121918464, COSV61004751, COSV61004889; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ASB10 | c.364G>T p.V122L (on ENST00000420175 / NM_001142459.2; = p.V107L on NM_080871.4) | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as rs1427635027; called by muse, mutect2
- ATP1A1 | c.2163C>A p.D721E | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CDHR4 | c.1647G>T p.E549D | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.247); called by muse, mutect2
- HEATR5B | c.1021C>G p.P341A | Missense Mutation (SNP) | VAF 52/98 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, varscan2
- MPHOSPH8 | c.2319C>A p.N773K | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2
- PLS3 | c.1133C>A p.P378Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SRSF2 | c.497_498insGCCC p.R167Pfs*49 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by pindel, varscan2
- PPP1R26 | c.2151G>A p.A717= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs527358949; called by muse, varscan2
- SPRR2B | c.189C>T p.C63= | Silent (SNP) | VAF 25/50 reads (50%) | catalogued as rs1035683029, COSV58797405; called by muse, mutect2, varscan2
- HOXA6 | chr7:27151582 C>A | 5'Flank (SNP) | VAF 4/30 reads (13%) | called by muse, varscan2
- NCF1C | n.312C>A | RNA (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- POM121L4P | n.415G>A | RNA (SNP) | VAF 20/117 reads (17%) | catalogued as rs200714508; called by muse, mutect2, varscan2
